EXCEPTIONAL_RESPONDERS case ER-B1T5 — Exceptional Responders (EXCEPTIONAL_RESPONDERS-ER)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Breast. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/322d2866-ed98-450a-b290-8db38b461568

Demographics
Sex at birth: female; Race: white; Ethnicity: not hispanic or latino; Year of birth: 1951; Vital status: Alive.

Diagnoses (1)
1. Ductal carcinoma, NOS: ICD-O-3 morphology code: 8500/3; Tissue or organ of origin: Breast, NOS; Site of resection or biopsy: Breast, NOS; Classification of tumor: primary; Age at diagnosis: 62.9 years (22,963 days); Year of diagnosis: 2014; AJCC pathologic stage: Stage IV; Prior malignancy: no; Days to last follow up: 1,295 days (3.5 years); Days to best overall response: 309 days; Best overall response: Partial Response.
   Treatment given: Therapeutic agents: Trastuzumab; Days to treatment start: 36 days; Days to treatment end: 1,295 days (3.5 years).

Follow-up (1 entry)
- Days to follow up: 1,295 days (3.5 years); Disease response: Clinical Progression; Progression or recurrence: Yes; Days to progression: 1,295 days (3.5 years); Days to recurrence: 2 days.

Biospecimens (1 sample; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample ER-B1T5-TTP1-B: Sample type: Slides; Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
  Slide ER-B1T5-TTP1-B-1-0-S1: Section location: Top; Percent tumor cells: 50; Percent tumor nuclei: 70; Percent normal cells: 0; Percent necrosis: 0; Percent stromal cells: 50; Percent lymphocyte infiltration: 0; Percent monocyte infiltration: 0; Percent neutrophil infiltration: 0.
